Somatic mutation profile of tumor specimen TARGET-10-PANTCR-09A (aliquot TARGET-10-PANTCR-09A-01D) from TARGET case TARGET-10-PANTCR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,059 days).
Specimen TARGET-10-PANTCR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f644a40-40cd-4eca-a6a7-eb237a107d17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTCR-10A (Blood Derived Normal), aliquot TARGET-10-PANTCR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03fe4eb0-5bbb-40d2-ba71-281fb71d3bc4

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Silent 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLK2 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57111085, COSV57111225, COSV99956166; called by muse, mutect2
- TSG101 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as rs536369381; called by muse, mutect2, varscan2
- CTNND2 | c.2980T>A p.S994T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FN1 | c.3462A>T p.Q1154H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SETD2 | c.2285C>G p.S762C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CELF5 | c.702G>A p.T234= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs779034828; called by muse, mutect2, varscan2
- DST | c.11997G>A p.K3999= (on ENST00000361203 / NM_001374722.1; = p.K1587= on NM_015548.5) | Silent (SNP) | VAF 5/104 reads (5%) | called by muse, mutect2
- ATP11AUN | n.1082G>T | RNA (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- FSIP2 | c.477+29T>G | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- KCNA2 | c.*1234C>G | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- RIPOR1 | c.579+26G>A | Intron (SNP) | VAF 3/60 reads (5%) | called by muse, mutect2
